MMRF case MMRF_2546 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7de402ad-469d-4ab4-bc9d-e546a9baf2dc

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Dead; Days to death: 438 days (1.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.6 years (29,793 days); ISS stage: III; Days to last known disease status: 438 days (1.2 years); Days to last follow up: 438 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 136 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 197 days; Days to treatment end: 366 days (1.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 438.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 0): M Protein 5.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 112 mg/dL; Immunoglobulin G 70.2 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 7.62 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 7.96 ×10⁹/L; Absolute Neutrophil 5.47 ×10⁹/L; Platelets 383 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 32 g/L; Total Protein 11 g/dL; Glucose 6.71 mmol/L.
- Day 61 (ECOG 0): M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 103 mg/dL; Immunoglobulin G 51.3 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 6.84 µg/mL; Hemoglobin 6.57 mmol/L; Leukocytes 5.49 ×10⁹/L; Absolute Neutrophil 2.91 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.18 mmol/L; Albumin 30 g/L; Total Protein 9.4 g/dL; Glucose 8.2 mmol/L.
- Day 170 (ECOG 0): M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 104 mg/dL; Immunoglobulin G 52 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 10.3 µg/mL; Hemoglobin 5.08 mmol/L; Leukocytes 6.34 ×10⁹/L; Absolute Neutrophil 4.08 ×10⁹/L; Platelets 348 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 10.2 g/dL; Glucose 12.9 mmol/L.
- Day 268 (ECOG 0): M Protein 5.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 238 mg/dL; Immunoglobulin G 66.2 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 13.4 µg/mL; Hemoglobin 5.77 mmol/L; Leukocytes 12.5 ×10⁹/L; Absolute Neutrophil 8.3 ×10⁹/L; Platelets 355 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.23 mmol/L; Albumin 25 g/L; Total Protein 10.9 g/dL; Glucose 3.25 mmol/L.
- Day 352 (ECOG 1): M Protein 6.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 191 mg/dL; Immunoglobulin G 73.4 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.27 mmol/L; Leukocytes 12.3 ×10⁹/L; Absolute Neutrophil 8.45 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.13 mmol/L; Albumin 24 g/L; Total Protein 11.4 g/dL; Glucose 19.5 mmol/L.
- Day 425 (ECOG 3): M Protein 8.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 238 mg/dL; Immunoglobulin G 87.4 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 4.96 mmol/L; Leukocytes 8.11 ×10⁹/L; Absolute Neutrophil 4.72 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 212 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.6 mmol/L; Albumin 22 g/L; Total Protein 13.1 g/dL; Glucose 7.76 mmol/L.

Other clinical attributes
- Day -20: Weight: 87 kg; Height: 177 cm.

Biospecimens (2 samples)
- Sample MMRF_2546_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2546_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
